Somatic mutation profile of tumor specimen TCGA-BF-A5EQ-01A (aliquot TCGA-BF-A5EQ-01A-21D-A27K-08) from TCGA case TCGA-BF-A5EQ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 63.9 years (23,353 days).
Specimen TCGA-BF-A5EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6af4d7fc-9263-48c1-b488-00ee0a15855a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-A5EQ-10A (Blood Derived Normal), aliquot TCGA-BF-A5EQ-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54c5381a-d255-46d4-b584-0c0c997f208b

The open-access MAF lists 696 somatic variants for this specimen: 467 protein-altering or splice-affecting, 214 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 430, Silent 214, Nonsense Mutation 23, Intron 7, Splice Site 5, Splice Region 4, Frame Shift Del 3, RNA 3, 5'UTR 2, 5'Flank 2, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 18/76 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57595738; called by muse, mutect2, varscan2
- ASNS | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754043007, CM163694, COSV99446791; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TACC3 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 44/127 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV57603049; called by muse, mutect2, varscan2
- UPF3B | c.1288C>T p.R430* (on ENST00000276201 / NM_080632.3; = p.R417* on NM_023010.3) | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as rs122468181, CM074621, COSV52229788; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7873A>T p.M2625L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV101447201; called by muse, mutect2, varscan2
- ABCC2 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as rs765749316, COSV64988539; called by muse, mutect2, varscan2
- ABCC3 | c.3958G>A p.G1320R | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99559780; called by muse, mutect2, varscan2
- ABCC9 | c.4120G>A p.G1374R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99687121; called by muse, mutect2, varscan2
- ABHD4 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99360614; called by muse, mutect2, varscan2
- ABHD4 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99360616; called by muse, mutect2, varscan2
- ABL1 | c.2225C>T p.S742F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as COSV100584571; called by muse, mutect2, varscan2
- ACAN | c.4958C>T p.P1653L | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV61367234; called by muse, mutect2, varscan2
- ACSM4 | c.1333A>C p.T445P | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV101257349; called by muse, mutect2, varscan2
- ACTL9 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.324); catalogued as rs782524837, COSV61005237; called by muse, mutect2, varscan2
- ADAM22 | c.1252A>C p.N418H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99718231; called by muse, mutect2, varscan2
- ADAMTS20 | c.1244A>C p.D415A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101240320; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99721086; called by muse, mutect2, varscan2
- ADCK2 | c.1370A>T p.N457I | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99301856; called by muse, mutect2, varscan2
- ADCY10 | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV100897080; called by muse, mutect2, varscan2
- ADGRF4 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99348942; called by muse, mutect2, varscan2
- ADGRG4 | c.4217C>A p.S1406Y | Missense Mutation (SNP) | VAF 46/58 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV54963095, COSV99796652; called by muse, mutect2, varscan2
- ADH1C | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV72463424; called by muse, mutect2, varscan2
- ADRA1A | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99372109; called by muse, mutect2, varscan2
- AFDN | c.4367C>T p.P1456L | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV100653517; called by muse, mutect2, varscan2
- AHNAK2 | c.14084T>A p.M4695K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.02); catalogued as COSV100318879; called by muse, mutect2, varscan2
- AHNAK2 | c.9157G>A p.E3053K | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.858); catalogued as rs1434057803, COSV60935522; called by muse, mutect2, varscan2
- AKAP17A | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as rs749621675, COSV100002481; called by muse, mutect2, varscan2
- AL162417.1 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV100923171; called by muse, mutect2, varscan2
- ALDH8A1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99665007; called by muse, mutect2, varscan2
- ALK | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV66586159; called by muse, mutect2, varscan2
- ALKBH4 | c.204C>A p.F68L | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99479543; called by muse, mutect2
- ALKBH8 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99509161; called by muse, mutect2, varscan2
- AMER2 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100766379; called by muse, mutect2, varscan2
- AMER3 | c.1904C>T p.P635L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV58465202; called by muse, mutect2, varscan2
- ANGPT1 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as COSV99863610, COSV99864109; called by muse, mutect2, varscan2
- ANGPTL5 | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100528001; called by muse, mutect2, varscan2
- ANKMY1 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs769318304, COSV56032278; called by muse, mutect2, varscan2
- ANKRD30A | c.4121T>C p.F1374S (on ENST00000611781; = p.F1318S on NM_052997.2) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV100654419; called by muse, mutect2, varscan2
- APOB | c.5151G>A p.M1717I | Missense Mutation (SNP) | VAF 57/195 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs148451559, COSV51933419, COSV99267917; called by muse, mutect2, varscan2
- APOB | c.4853C>T p.S1618L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1021781662, COSV99267922; called by muse, mutect2, varscan2
- AQP8 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV54844330, COSV54846781; called by muse, mutect2, varscan2
- ARGFX | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100544209; called by muse, mutect2, varscan2
- ARHGAP4 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 70/106 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as COSV100604228; called by muse, mutect2, varscan2
- ARHGAP5 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV100565685; called by muse, mutect2, varscan2
- ARSH | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101139708; called by muse, mutect2, varscan2
- ASPA | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs745553536, COSV99559328; called by muse, mutect2
- ASXL3 | c.2267C>T p.S756F | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV52483878; called by muse, mutect2, varscan2
- ASXL3 | c.4108C>T p.P1370S | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs1349869581, COSV52458378; called by muse, mutect2, varscan2
- ASXL3 | c.5138C>T p.S1713L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.024); catalogued as COSV99326474; called by muse, mutect2, varscan2
- ATP2B2 | c.2248G>A p.E750K (on ENST00000352432; = p.E716K on NM_001683.5) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV100660448; called by muse, mutect2
- ATP8A1 | c.3008G>A p.W1003* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100047270; called by muse, mutect2, varscan2
- ATRNL1 | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.37); PolyPhen probably damaging (1); catalogued as rs782137157, COSV100746885; called by muse, mutect2, varscan2
- B4GALNT3 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs745978354, COSV99843577; called by muse, mutect2, varscan2
- BAAT | c.1103A>G p.Y368C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs748741360, COSV99408660; called by muse, mutect2, varscan2
- BDKRB2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs772874206, COSV100021300, COSV60016124; called by muse, mutect2, varscan2
- BHMT | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.488); catalogued as COSV99165519; called by muse, mutect2, varscan2
- BMP2 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV101122116; called by muse, mutect2, varscan2
- BMP2 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV66576987; called by muse, mutect2, varscan2
- BRINP1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56299172; called by muse, mutect2, varscan2
- C10orf71 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1436845275, COSV100110626; called by muse, mutect2, varscan2
- C14orf39 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1227460686, COSV58779571; called by muse, mutect2, varscan2
- C1orf127 | c.1694G>A p.G565D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100983516; called by muse, mutect2, varscan2
- C4B | c.3893G>A p.G1298E | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101312309; called by muse, mutect2, varscan2
- C8B | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.426); catalogued as rs1454127530, COSV100980906; called by muse, mutect2, varscan2
- C9 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99662524; called by muse, mutect2, varscan2
- CACNA1B | c.6757C>T p.R2253* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as rs866465218, COSV53154633; called by muse, mutect2, varscan2
- CACNA2D2 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1419557043, COSV56568003; called by muse, mutect2, varscan2
- CAPZA3 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as rs761872921, COSV56855818; called by muse, mutect2, varscan2
- CASP7 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs866310961, COSV100615030; called by muse, mutect2, varscan2
- CATSPERE | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs763977146, COSV100835371; called by muse, mutect2, varscan2
- CCDC136 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.475); catalogued as COSV99923176; called by muse, mutect2, varscan2
- CCDC191 | c.1436G>A p.W479* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as COSV99878739; called by muse, mutect2, varscan2
- CCDC197 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV100113700; called by muse, mutect2, varscan2
- CCDC54 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV99660328; called by muse, mutect2, varscan2
- CCDC60 | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.724); catalogued as COSV100554564; called by muse, mutect2, varscan2
- CCNT2 | c.241-1G>A p.X81_splice | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99751177; called by muse, mutect2, varscan2
- CD163 | c.3333G>A p.M1111I | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs868449455, COSV63137008; called by muse, mutect2, varscan2
- CDC45 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1337073064, COSV99597028; called by muse, mutect2, varscan2
- CDH15 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773680931, COSV57025741; called by muse, mutect2, varscan2
- CDH16 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100234177; called by muse, mutect2, varscan2
- CEP63 | c.1972C>T p.P658S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.421); catalogued as COSV100133097; called by muse, mutect2, varscan2
- CERS3 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1011622454, COSV52573465; called by muse, mutect2, varscan2
- CFAP47 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.335); catalogued as COSV99935799; called by muse, mutect2, varscan2
- CFL1 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100354162; called by muse, mutect2, varscan2
- CHD6 | c.7397C>T p.P2466L | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100951358; called by muse, mutect2, varscan2
- CHRM5 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101272049; called by muse, mutect2, varscan2
- CHRNA2 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV53558101; called by muse, mutect2, varscan2
- CHRNA9 | c.124T>C p.Y42H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100039113; called by muse, mutect2, varscan2
- CIZ1 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV99477124; called by muse, mutect2, varscan2
- CMYA5 | c.5422G>A p.E1808K | Missense Mutation (SNP) | VAF 72/118 reads (61%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.052); catalogued as COSV101484354; called by muse, mutect2, varscan2
- CNGA4 | c.1714C>T p.P572S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs774959732, COSV101171874; called by muse, mutect2, varscan2
- CNTNAP2 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 91/169 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); catalogued as rs1342844761, COSV100672139; called by muse, mutect2, varscan2
- COL22A1 | c.2786C>T p.P929L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV57341154; called by muse, mutect2, varscan2
- COL4A1 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011364, COSV101011562; called by muse, mutect2, varscan2
- COL5A1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.035); catalogued as COSV100880565, COSV100880753; called by muse, mutect2, varscan2
- COL6A3 | c.9445G>A p.E3149K | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs138694883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORIN | c.2833G>A p.G945R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56702311, COSV99904597; called by muse, mutect2
- COX15 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV99187565; called by muse, mutect2, varscan2
- CP | c.778T>C p.Y260H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99224448; called by muse, mutect2, varscan2
- CPNE6 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.061); catalogued as rs377488418; called by muse, mutect2, varscan2
- CRB1 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100958073; called by muse, mutect2, varscan2
- CSMD1 | c.7837G>A p.D2613N (on ENST00000520002; = p.D2612N on NM_033225.6) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs758159540, COSV59363879; called by muse, mutect2, varscan2
- CSMD1 | c.2913G>A p.M971I (on ENST00000520002; = p.M970I on NM_033225.6) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.921); catalogued as COSV59285935; called by muse, mutect2
- CSMD2 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV53944609; called by muse, mutect2, varscan2
- CSMD3 | c.3859C>T p.H1287Y (on ENST00000297405 / NM_001363185.1; = p.H1183Y on NM_052900.3) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99833467; called by muse, mutect2, varscan2
- CTAGE1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.249); catalogued as COSV66945653; called by muse, mutect2, varscan2
- CTNNA2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as rs945046536, COSV63582059; called by muse, mutect2, varscan2
- CTSS | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs764417853, COSV64566046; called by muse, mutect2, varscan2
- CYLD | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61092812; called by muse, mutect2, varscan2
- CYP11B2 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as COSV100010983, COSV59994417; called by muse, mutect2, varscan2
- CYP3A4 | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV60502034; called by muse, mutect2, varscan2
- CYP7A1 | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.159); catalogued as COSV100052631; called by muse, mutect2, varscan2
- DDX23 | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as COSV99975108; called by muse, mutect2, varscan2
- DGKG | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs779847882, COSV53965486; called by muse, mutect2, varscan2
- DICER1 | c.5240C>T p.S1747L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58625060; called by muse, mutect2, varscan2
- DLC1 | c.606A>G p.I202M | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.07); catalogued as COSV99365376; called by muse, mutect2, varscan2
- DLEC1 | c.3536C>T p.S1179F | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100343422; called by muse, mutect2, varscan2
- DMBT1 | c.4969G>A p.G1657S (on ENST00000338354 / NM_001377530.1; = p.G900S on NM_004406.3) | Missense Mutation (SNP) | VAF 55/383 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100354054; called by muse, varscan2
- DMBT1 | c.5066G>A p.G1689E (on ENST00000338354 / NM_001377530.1; = p.G932E on NM_004406.3) | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs751105407, COSV100354055; called by muse, varscan2
- DMXL2 | c.4417C>G p.Q1473E | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.493); catalogued as COSV99198549; called by muse, mutect2
- DNAH1 | c.6617C>T p.T2206I | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101327019; called by muse, mutect2, varscan2
- DNAH2 | c.3886T>C p.F1296L | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101209584; called by muse, mutect2, varscan2
- DNAH5 | c.2980C>T p.R994W | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs560275492, COSV54217714; called by muse, mutect2, varscan2
- DNAH7 | c.5989G>A p.E1997K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.201); catalogued as rs764627328, COSV56751758, COSV56772679; called by muse, mutect2, varscan2
- DNAJC5B | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV52538627; called by muse, mutect2, varscan2
- DSC2 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99199864; called by muse, mutect2, varscan2
- DSCAML1 | c.2042C>T p.S681L (on ENST00000321322; = p.S621L on NM_020693.4) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.768); catalogued as rs374601359; called by muse, mutect2, varscan2
- DSE | c.1874G>A p.S625N | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762921516, COSV100528796; called by muse, mutect2, varscan2
- DSG4 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV57391797; called by muse, mutect2, varscan2
- DSP | c.4093C>T p.Q1365* | Nonsense Mutation (SNP) | VAF 52/103 reads (50%) | catalogued as COSV101131742; called by muse, mutect2, varscan2
- DSP | c.8143G>A p.E2715K | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.066); catalogued as COSV60940408; called by mutect2, varscan2
- DVL2 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs151191814; called by muse, mutect2, varscan2
- EBF3 | c.787C>T p.P263S (on ENST00000355311 / NM_001375392.1; = p.P254S on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62482640; called by muse, mutect2, varscan2
- EFNB3 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99872970; called by muse, mutect2, varscan2
- EGFL6 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 50/71 reads (70%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.618); catalogued as COSV100789959; called by muse, mutect2, varscan2
- EGLN1 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100791326; called by muse, mutect2, varscan2
- EIF2AK3 | c.1306C>T p.H436Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs761048614, COSV57550417; called by muse, mutect2, varscan2
- ELFN2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as rs200557041, COSV68743789; called by muse, mutect2, varscan2
- ELSPBP1 | c.413A>T p.N138I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.328); catalogued as COSV100353771; called by muse, mutect2, varscan2
- EXD3 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.686); catalogued as COSV59813203; called by muse, mutect2, varscan2
- EXPH5 | c.4313C>T p.S1438F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as rs542108290, COSV99762168; called by muse, mutect2
- EYA2 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.605); catalogued as COSV57943984; called by muse, mutect2, varscan2
- FAHD2A | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs1426304239, COSV99272263; called by muse, mutect2, varscan2
- FAM160B1 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV100985576; called by muse, mutect2, varscan2
- FAM171B | c.2319G>T p.E773D | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.446); catalogued as COSV100488991; called by muse, mutect2, varscan2
- FAM83E | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as rs745322852, COSV99320389; called by muse, mutect2, varscan2
- FAP | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.033); catalogued as COSV99502531; called by muse, mutect2, varscan2
- FBLN1 | c.785-1G>T p.X262_splice | Splice Site (SNP) | VAF 18/75 reads (24%) | catalogued as COSV99411343, COSV99411434; called by muse, mutect2, varscan2
- FCRL5 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 74/215 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as COSV100709308; called by muse, mutect2, varscan2
- FERMT1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54090904; called by muse, mutect2, varscan2
- FILIP1 | c.3263C>T p.P1088L | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99386085; called by muse, mutect2, varscan2
- FKBP8 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.227); catalogued as COSV99724263; called by muse, mutect2, varscan2
- FLNC | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57958898; called by muse, mutect2, varscan2
- FLNC | c.7177C>T p.P2393S | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV100368703; called by muse, mutect2, varscan2
- FREM2 | c.5923G>A p.E1975K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99750689; called by muse, mutect2, varscan2
- FRMPD2 | c.2227G>A p.D743N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV59719091; called by muse, mutect2
- FRRS1L | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.993); catalogued as rs753224453, COSV73746608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FSIP2 | c.19415C>T p.S6472L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV100556413; called by muse, mutect2, varscan2
- FSTL5 | c.2299C>T p.L767F | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100060778; called by muse, mutect2, varscan2
- GCSAML | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100825879, COSV63579149; called by muse, mutect2, varscan2
- GDE1 | c.918A>C p.E306D | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99572848; called by muse, mutect2, varscan2
- GFRA2 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761015721, COSV100152074; called by muse, mutect2, varscan2
- GJA8 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.257); catalogued as COSV99569684; called by muse, mutect2
- GLP2R | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV99302451; called by muse, mutect2, varscan2
- GPR42 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101497384; called by muse, mutect2, varscan2
- GRB7 | c.156G>A p.R52= | Splice Region (SNP) | VAF 26/136 reads (19%) | catalogued as COSV100485648; called by muse, mutect2, varscan2
- GRIK3 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100902303; called by muse, mutect2, varscan2
- GRM7 | c.1673T>A p.M558K | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100738421; called by muse, mutect2, varscan2
- GUCY1A1 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.789); catalogued as rs772453526, COSV56649256, COSV56653947; called by muse, mutect2, varscan2
- GUCY2F | c.1941A>T p.K647N | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99485611; called by muse, mutect2, varscan2
- GXYLT1 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as COSV55136974; called by muse, mutect2, varscan2
- GYS2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs376712209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GZMH | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as COSV99362051; called by muse, varscan2
- H1-4 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.999); catalogued as rs771979983, COSV99175382; called by muse, mutect2, varscan2
- HCN4 | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as COSV99984201; called by muse, mutect2, varscan2
- HDAC9 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV101287439; called by muse, mutect2, varscan2
- HEPHL1 | c.2770G>A p.E924K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV59894892; called by muse, mutect2, varscan2
- HHIPL2 | c.972G>A p.E324= | Splice Region (SNP) | VAF 66/613 reads (11%) | catalogued as rs748099946, COSV100597095; called by muse, mutect2, varscan2
- HNF4A | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV100291714; called by muse, mutect2, varscan2
- HS3ST4 | c.829A>C p.M277L | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100502920; called by muse, mutect2, varscan2
- HUNK | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs141493785; called by muse, mutect2, varscan2
- HYDIN | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1204241946, COSV55476162, COSV55481735; called by muse, mutect2, varscan2
- IFNW1 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 60/159 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs769805510, COSV101207651; called by muse, mutect2, varscan2
- IFRD1 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs1380955120, COSV99134372; called by muse, mutect2, varscan2
- IGKV1-12 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs1327165229; called by muse, mutect2, varscan2
- IGKV2D-28 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV101494567; called by mutect2, varscan2
- IGLV3-10 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs774627600; called by muse, mutect2, varscan2
- IL10RA | c.1194G>T p.Q398H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV99923270; called by muse, mutect2, varscan2
- IL22 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.043); catalogued as rs781168624, COSV100048943; called by muse, mutect2, varscan2
- IP6K2 | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.017); catalogued as COSV99584247; called by muse, mutect2, varscan2
- IQUB | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 52/269 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV61243623; called by muse, mutect2, varscan2
- ITIH1 | c.2712T>A p.D904E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99835614; called by muse, mutect2, varscan2
- KALRN | c.1202A>T p.K401M | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99567179; called by muse, mutect2, varscan2
- KANK4 | c.2392G>A p.V798M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100443327; called by muse, mutect2, varscan2
- KCNB2 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV73053597; called by muse, mutect2, varscan2
- KCND3 | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.705); catalogued as COSV100138400; called by muse, mutect2, varscan2
- KCNJ3 | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV99716421; called by muse, mutect2, varscan2
- KCNQ2 | c.2582C>T p.P861L (on ENST00000359125 / NM_172107.4; = p.P833L on NM_004518.6) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.266); catalogued as COSV100610538; called by muse, mutect2, varscan2
- KEL | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100786813, COSV62337029; called by muse, mutect2, varscan2
- KIAA1109 | c.11842C>T p.P3948S | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.505); catalogued as COSV52668607; called by muse, mutect2, varscan2
- KIF1A | c.4508C>A p.S1503Y (on ENST00000320389 / NM_001379639.1; = p.S1495Y on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100242257, COSV57491818; called by muse, mutect2, varscan2
- KIF4B | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs565698502, COSV70528170; called by muse, mutect2, varscan2
- KLK7 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV100304496; called by muse, mutect2, varscan2
- KRT6B | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.065); catalogued as COSV99360977; called by muse, mutect2, varscan2
- KRT73 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs754038667, COSV59839354; called by muse, mutect2, varscan2
- KRT79 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs957307838, COSV57942855; called by muse, mutect2, varscan2
- KRTAP13-4 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100481829; called by muse, mutect2, varscan2
- LAMA1 | c.4391C>T p.P1464L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.393); catalogued as COSV67534102; called by muse, mutect2
- LAMB1 | c.3445G>A p.G1149S | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99741631; called by muse, mutect2, varscan2
- LEP | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.598); catalogued as COSV100451471; called by muse, mutect2, varscan2
- LIFR | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99665436; called by muse, mutect2, varscan2
- LILRB5 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60256682, COSV60257283; called by muse, mutect2, varscan2
- LIPE | c.2551C>T p.R851C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs756096337, COSV54923201; called by muse, mutect2, varscan2
- LPA | c.2632C>T p.P878S | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1190907967, COSV60315797; called by muse, mutect2, varscan2
- LPP | c.404C>A p.S135Y | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs767696813, COSV57089407; called by muse, mutect2, varscan2
- LRP1B | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.82); catalogued as COSV101260610, COSV67186606; called by muse, mutect2, varscan2
- LRP8 | c.2785G>T p.E929* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV100036896; called by muse, mutect2, varscan2
- LRR1 | c.487T>A p.Y163N | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV100023295; called by muse, mutect2
- LRRC6 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99138560; called by muse, mutect2, varscan2
- LRRK1 | c.5672C>T p.S1891F | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.259); catalogued as COSV99442981; called by muse, mutect2, varscan2
- LSP1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV100289532; called by muse, mutect2
- LTBP1 | c.3454G>A p.A1152T (on ENST00000404816 / NM_206943.4; = p.A826T on NM_000627.4) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.338); catalogued as rs762837064, COSV99698804; called by muse, mutect2, varscan2
- LUZP2 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as COSV100421298; called by muse, mutect2, varscan2
- LY9 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99627415; called by muse, mutect2, varscan2
- LZTS2 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100932276; called by muse, mutect2, varscan2
- MADD | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100211945; called by muse, mutect2, varscan2
- MAN1A1 | c.1831T>A p.L611M | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100870750; called by muse, mutect2, varscan2
- MAN2A2 | c.2026C>T p.L676F | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as rs267604385, COSV64638117; called by muse, mutect2, varscan2
- MAP7 | c.1855-1G>A p.X619_splice | Splice Site (SNP) | VAF 38/130 reads (29%) | catalogued as COSV100644021; called by muse, mutect2, varscan2
- MAPK4 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.288); catalogued as rs267605202, COSV101245966; called by muse, mutect2, varscan2
- MAPRE3 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs768144243, COSV99252014; called by muse, mutect2, varscan2
- MARCO | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1218165315, COSV100503832; called by muse, mutect2, varscan2
- MARK1 | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs145170499, COSV65070322; called by muse, mutect2, varscan2
- MAS1 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.254); catalogued as rs1440765163, COSV53120592; called by muse, mutect2, varscan2
- MATN4 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | PolyPhen benign (0.001); catalogued as COSV59213417; called by muse, mutect2, varscan2
- MCM7 | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100385150; called by muse, mutect2, varscan2
- MCTP1 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1427351043, COSV56537002; called by muse, mutect2, varscan2
- ME1 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs1267932567, COSV100866689; called by muse, mutect2, varscan2
- MEGF11 | c.2059G>A p.G687R | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474812821, COSV99989148; called by muse, mutect2, varscan2
- MGAM | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101527738; called by muse, mutect2
- MGAM | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782316099, COSV101527739; called by muse, mutect2
- MGRN1 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as rs752737830, COSV99274809; called by muse, mutect2, varscan2
- MIA2 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.461); catalogued as rs942254770, COSV54484273; called by muse, mutect2, varscan2
- MMP13 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs1413504149, COSV52825684; called by muse, mutect2, varscan2
- MNX1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs1392587828, COSV99429816; called by muse, mutect2, varscan2
- MORC1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV51728768, COSV99224933; called by muse, mutect2, varscan2
- MORC2 | c.1805C>T p.S602F (on ENST00000397641 / NM_001303256.3; = p.S540F on NM_014941.3) | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.31); PolyPhen benign (0.069); catalogued as COSV99310406; called by muse, mutect2, varscan2
- MRPL1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.093); catalogued as rs745810053, COSV59673734; called by muse, mutect2, varscan2
- MSH4 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99592500; called by muse, mutect2, varscan2
- MTMR12 | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99374035; called by muse, mutect2, varscan2
- MTMR4 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs774937766, COSV100051427; called by muse, mutect2, varscan2
- MTTP | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99645567; called by muse, mutect2, varscan2
- MTUS2 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs748162135, COSV101462362; called by muse, mutect2, varscan2
- MTX2 | c.546C>T p.V182= | Splice Region (SNP) | VAF 88/314 reads (28%) | catalogued as COSV99981380; called by muse, mutect2, varscan2
- MUC16 | c.24178G>A p.D8060N | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.125); catalogued as rs541350099, COSV101198208; called by muse, mutect2, varscan2
- MUC17 | c.7852G>T p.A2618S | Missense Mutation (SNP) | VAF 114/463 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.739); catalogued as COSV100074975, COSV60295777; called by muse, mutect2, varscan2
- MUC5AC | c.14128G>A p.G4710R | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100611591; called by muse, mutect2, varscan2
- MXRA5 | c.7289C>T p.T2430M | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs376795964, COSV54235079; called by muse, mutect2, varscan2
- MYH1 | c.5311G>A p.E1771K | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV99876824; called by muse, mutect2, varscan2
- MYH2 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99820922; called by muse, mutect2, varscan2
- MYO18B | c.3368G>A p.R1123K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.793); catalogued as COSV100125097; called by muse, mutect2, varscan2
- MYOM1 | c.3494C>T p.P1165L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as COSV99868307; called by muse, mutect2, varscan2
- NCKAP1L | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV99515653; called by muse, mutect2, varscan2
- NCOA1 | c.3064C>G p.P1022A | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV99947028; called by muse, mutect2, varscan2
- NEFH | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100151809; called by muse, mutect2, varscan2
- NLN | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 88/159 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV66767104; called by muse, mutect2, varscan2
- NLRP3 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.053); catalogued as rs768966147, COSV60222235; called by muse, mutect2, varscan2
- NMD3 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.317); catalogued as COSV100664804; called by muse, mutect2, varscan2
- NOL6 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.415); catalogued as COSV99955185; called by muse, mutect2, varscan2
- NOS3 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as rs1003496315, COSV99872138; called by muse, mutect2, varscan2
- NPAP1 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100276159; called by mutect2, varscan2
- NPHS1 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV100799763; called by muse, mutect2, varscan2
- NRP1 | c.1855C>T p.Q619* | Nonsense Mutation (SNP) | VAF 22/53 reads (42%) | catalogued as COSV99589584; called by muse, mutect2, varscan2
- NXPH3 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165582; called by muse, mutect2, varscan2
- NYNRIN | c.4819C>T p.P1607S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.113); catalogued as COSV101230699; called by muse, mutect2, varscan2
- OBSCN | c.10510G>A p.E3504K | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); catalogued as COSV99484044; called by muse, mutect2, varscan2
- ODF3L1 | c.105G>A p.M35I | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs1271439171, COSV100150835; called by muse, mutect2, varscan2
- OOSP2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs267603047, COSV53929740; called by muse, mutect2, varscan2
- OR10A2 | c.712T>A p.F238I | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100225176; called by muse, mutect2, varscan2
- OR10G4 | c.474G>C p.Q158H | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.828); catalogued as COSV100304985; called by muse, mutect2, varscan2
- OR10R2 | c.588T>A p.H196Q | Missense Mutation (SNP) | VAF 7/195 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100936842; called by muse, mutect2
- OR12D3 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs1354110260, COSV65828818; called by muse, mutect2, varscan2
- OR1D2 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100513974; called by muse, mutect2, varscan2
- OR1N1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.801); catalogued as COSV100509833, COSV59195768; called by muse, mutect2, varscan2
- OR2W1 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV65851528; called by muse, mutect2, varscan2
- OR51L1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs536613890, COSV100386487; called by muse, mutect2, varscan2
- OR52B4 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs184336656, COSV101281609; called by muse, mutect2, varscan2
- OR8B8 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100045242; called by muse, mutect2, varscan2
- OR8K3 | c.684G>A p.M228I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as rs866838400, COSV57133087; called by muse, mutect2, varscan2
- OXCT2 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.918); catalogued as rs1262186887, COSV59593559, COSV59594750; called by muse, mutect2, varscan2
- PANK2 | c.1144C>T p.P382S (on ENST00000316562 / NM_153638.3; = p.P91S on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV100262499; called by muse, mutect2, varscan2
- PAPPA2 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV100867457; called by muse, mutect2, varscan2
- PAX2 | c.935A>G p.N312S (on ENST00000428433 / NM_003987.5; = p.N289S on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV100695425; called by muse, mutect2, varscan2
- PAX6 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53794926; called by muse, mutect2
- PCDHA5 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); catalogued as COSV65358527; called by muse, varscan2
- PCLO | c.8185G>A p.D2729N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100437547; called by muse, mutect2, varscan2
- PCNT | c.3332C>T p.S1111F | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs775970977, COSV100856019; called by muse, mutect2, varscan2
- PCNX2 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1471016554, COSV50854845; called by muse, mutect2, varscan2
- PDE3A | c.2208G>A p.M736I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV100762755; called by muse, mutect2, varscan2
- PDZD2 | c.2599C>T p.Q867* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV99226619; called by muse, mutect2, varscan2
- PEAR1 | c.2855G>A p.G952E | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs774252576, COSV52774819; called by muse, mutect2, varscan2
- PGBD2 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs1182987909, COSV100252240; called by muse, mutect2, varscan2
- PGK2 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV59164887; called by muse, mutect2, varscan2
- PHIP | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs752534420, COSV99244862; called by muse, mutect2, varscan2
- PI3 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.427); catalogued as COSV54783188; called by muse, mutect2
- PIK3AP1 | c.1763G>A p.R588K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0.415); catalogued as COSV100226202; called by muse, mutect2, varscan2
- PIK3C3 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.278); catalogued as COSV100011575; called by muse, mutect2, varscan2
- PKD1 | c.4525G>A p.E1509K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0.104); catalogued as rs776253432, CM1413091, COSV51920221; called by muse, mutect2, varscan2
- PLA2G4E | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs567649717, COSV68149047, COSV68149931; called by muse, mutect2, varscan2
- PLA2R1 | c.1999G>A p.D667N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs769938979, COSV104392951, COSV99323549; called by muse, mutect2, varscan2
- PLA2R1 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV51777367; called by muse, mutect2, varscan2
- PLAAT5 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV57137826; called by muse, mutect2
- PLEKHG3 | c.2461C>T p.P821S (on ENST00000394691; = p.P877S on NM_001308147.2) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs1197863306, COSV99906898; called by muse, mutect2, varscan2
- PLXDC2 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65909531; called by muse, mutect2, varscan2
- PNPLA6 | c.1160C>T p.P387L (on ENST00000414982 / NM_001166111.2; = p.P339L on NM_006702.5) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1362018954, COSV99654484; called by muse, mutect2
- POLR3C | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100493099; called by muse, mutect2, varscan2
- POMT2 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV55071306; called by muse, mutect2, varscan2
- POTEF | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV100664408, COSV100665327; called by muse, mutect2, varscan2
- PPIA | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); catalogued as rs1164610556, COSV63534314; called by muse, mutect2, varscan2
- PPIG | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as COSV53644371, COSV99644917; called by muse, mutect2, varscan2
- PPP1CC | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV100534969; called by muse, mutect2, varscan2
- PRB3 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 158/482 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs764834666, COSV54387759; called by muse, mutect2, varscan2
- PRKAR2A | c.410T>A p.I137N | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.701); catalogued as COSV99605489; called by muse, mutect2, varscan2
- PRKCQ | c.2059G>A p.D687N | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.998); catalogued as COSV99577798; called by muse, mutect2, varscan2
- PRMT5 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV99363158; called by muse, mutect2, varscan2
- PRODH2 | c.1188G>A p.M396I (on ENST00000301175; = p.M320I on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99995513; called by muse, mutect2, varscan2
- PRSS54 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs780162055, COSV54685382; called by muse, mutect2, varscan2
- PRX | c.1798C>G p.L600V | Missense Mutation (SNP) | VAF 108/273 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.341); catalogued as COSV99398038; called by muse, mutect2, varscan2
- PTCH2 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV100942269; called by muse, mutect2, varscan2
- PTPRB | c.5824C>T p.H1942Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99718876; called by muse, mutect2, varscan2
- PTPRE | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV99618996; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs776122879, COSV54575196; called by muse, mutect2, varscan2
- RAPGEF5 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100687843; called by muse, mutect2, varscan2
- RASGRF2 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 138/189 reads (73%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.884); catalogued as rs772894520, COSV99430293; called by muse, mutect2, varscan2
- RASSF10 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.137); catalogued as COSV61754363; called by muse, mutect2, varscan2
- RBM6 | c.3121C>T p.R1041C | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs759507731, COSV56489163; called by muse, mutect2, varscan2
- RBP1 | c.274G>A p.D92N (on ENST00000619087 / NM_001365940.2; = p.D154N on NM_002899.5) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.94); catalogued as COSV99219121; called by muse, mutect2, varscan2
- RCL1 | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.16); catalogued as rs148074533; called by muse, mutect2, varscan2
- RCSD1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV100827531, COSV100827784; called by muse, mutect2, varscan2
- REPS1 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99239014; called by muse, mutect2, varscan2
- RETNLB | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.388); catalogued as COSV99848904; called by muse, mutect2, varscan2
- RFX3 | c.268G>T p.G90* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100175787; called by muse, mutect2, varscan2
- RGPD1 | c.3988G>A p.E1330K (on ENST00000409776; = p.E1338K on NM_001024457.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as COSV101233693; called by muse, mutect2, varscan2
- RIMKLA | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV101343486; called by muse, mutect2, varscan2
- RNF166 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs765947541, COSV57190219; called by muse, mutect2, varscan2
- ROBO4 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs775011073, COSV60624436; called by muse, mutect2, varscan2
- RP1 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV99608789; called by muse, mutect2
- RPN2 | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99412032; called by muse, mutect2, varscan2
- RXFP1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100314177; called by muse, mutect2, varscan2
- RYR2 | c.14494G>A p.E4832K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1443988544, COSV63658068; called by muse, mutect2, varscan2
- RYR3 | c.5743G>A p.E1915K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV101214415; called by muse, mutect2
- RYR3 | c.9343G>A p.D3115N (on ENST00000389232; = p.D3116N on NM_001036.6) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs762199883, COSV66790414; called by muse, mutect2, varscan2
- SAAL1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as COSV100254036; called by muse, mutect2, varscan2
- SALL1 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99183967; called by muse, mutect2, varscan2
- SASH1 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1378777761, COSV100821436; called by muse, mutect2, varscan2
- SCN3B | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV100173858; called by muse, mutect2, varscan2
- SEC14L5 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99229399; called by muse, mutect2, varscan2
- SEC24D | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763522207, COSV54883744; called by muse, mutect2
- SERPINB6 | c.1184C>T p.P395L (on ENST00000612421 / NM_001271823.2; = p.P376L on NM_004568.6) | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369004254; called by muse, mutect2, varscan2
- SERPINB6 | c.1183C>T p.P395S (on ENST00000612421 / NM_001271823.2; = p.P376S on NM_004568.6) | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758863651, COSV59566717; called by muse, mutect2, varscan2
- SETD7 | c.51C>G p.D17E | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99918697; called by muse, mutect2, varscan2
- SHPRH | c.3038G>A p.G1013E (on ENST00000275233 / NM_001042683.3; = p.G1022E on NM_173082.3) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.367); catalogued as rs1036921728, COSV99262661; called by muse, mutect2, varscan2
- SIGLEC8 | c.1266G>A p.W422* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as rs267605612, COSV58472074, COSV58473656; called by muse, mutect2, varscan2
- SLC10A7 | c.472-1G>A p.X158_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99391052; called by muse, mutect2, varscan2
- SLC12A8 | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100103118, COSV100103282; called by muse, mutect2
- SLC1A5 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV101314820; called by muse, mutect2, varscan2
- SLC1A5 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101314821; called by muse, mutect2, varscan2
- SLC22A2 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.637); catalogued as COSV65266044, COSV65267697; called by muse, mutect2, varscan2
- SLC6A3 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99548831; called by muse, mutect2, varscan2
- SLC8A1 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100247374; called by muse, mutect2, varscan2
- SLCO2A1 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100189329; called by muse, mutect2, varscan2
- SMCO1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.439); catalogued as COSV101285033, COSV104433337; called by muse, mutect2, varscan2
- SMG7 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 111/223 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100750048; called by muse, mutect2, varscan2
- SNAP91 | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV52118664; called by muse, mutect2, varscan2
- SNX31 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771237789, COSV100310503; called by muse, mutect2, varscan2
- SORCS1 | c.3431G>T p.R1144L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99550111; called by muse, mutect2, varscan2
- SP1 | c.2330C>T p.S777F (on ENST00000327443 / NM_138473.3; = p.S770F on NM_003109.1) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV100540851; called by muse, mutect2, varscan2
- SPAG1 | c.1549C>T p.H517Y | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99309463; called by muse, mutect2, varscan2
- SPATA20 | c.2275C>T p.Q759* (on ENST00000356488 / NM_001258372.1; = p.Q775* on NM_022827.4) | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as rs867194968, COSV99136654; called by muse, mutect2, varscan2
- SPTSSB | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs766616228, COSV63218975; called by muse, mutect2, varscan2
- STAB2 | c.3104C>T p.S1035F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778993122, COSV66333512; called by muse, mutect2, varscan2
- STARD13 | c.1327G>A p.E443K (on ENST00000336934 / NM_001243476.3; = p.E325K on NM_052851.3) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV99716365; called by muse, mutect2, varscan2
- STK31 | c.1777C>T p.H593Y | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs755196083, COSV100669118; called by muse, mutect2, varscan2
- STK36 | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV55331766; called by muse, mutect2, varscan2
- TAF5 | c.1682C>T p.S561F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV100428302; called by muse, mutect2, varscan2
- TBC1D1 | c.2558-1G>A p.X853_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99792133; called by muse, mutect2, varscan2
- TBC1D9B | c.2788C>T p.P930S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100783648; called by muse, mutect2, varscan2
- TBCEL | c.837C>T p.A279= | Splice Region (SNP) | VAF 15/102 reads (15%) | catalogued as COSV99412405; called by muse, mutect2, varscan2
- TDRD5 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); catalogued as rs1167156592, COSV99677113; called by muse, mutect2, varscan2
- TEC | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.876); catalogued as COSV101202683; called by muse, mutect2, varscan2
- TEK | c.3296G>A p.R1099Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs759970580, COSV66231648; called by muse, mutect2, varscan2
- TENM3 | c.2603G>A p.R868K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV69298298, COSV69309871; called by muse, mutect2, varscan2
- TET2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as COSV99484684; called by muse, mutect2, varscan2
- TET2 | c.2837C>T p.T946I | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1359281257, COSV99484686; called by muse, mutect2, varscan2
- TEX37 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs746814303, COSV100304682; called by muse, mutect2, varscan2
- TFDP3 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.15); catalogued as COSV100033540, COSV59536670; called by muse, mutect2, varscan2
- TFEC | c.13C>T p.H5Y | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV55408127; called by muse, mutect2
- THADA | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.469); catalogued as rs770322476, COSV100369442; called by muse, mutect2, varscan2
- THSD7A | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1209387305, COSV70263944; called by muse, mutect2, varscan2
- TIAM2 | c.3127G>A p.D1043N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as COSV100020074; called by muse, mutect2, varscan2
- TK2 | c.512C>T p.P171L (on ENST00000299697; = p.P227L on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs754140768, COSV100228051, COSV100228268; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLN1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV100148225; called by muse, mutect2, varscan2
- TMC3 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63922099; called by muse, mutect2, varscan2
- TMPRSS11B | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs773181040, COSV100219520; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV100552667; called by muse, mutect2, varscan2
- TNFRSF13B | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99890807; called by muse, mutect2, varscan2
- TNN | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs776834667, COSV53426449, COSV99513441; called by muse, mutect2, varscan2
- TRAF3IP2 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100389890; called by muse, mutect2, varscan2
- TRAV26-1 | c.41G>A p.G14E | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1433701912; called by muse, mutect2, varscan2
- TRERF1 | c.2033C>T p.S678L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as rs772638924, COSV100550136; called by muse, mutect2, varscan2
- TRERF1 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV100551608; called by muse, mutect2, varscan2
- TRPM8 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.045); catalogued as rs759082023, COSV100224521; called by muse, mutect2, varscan2
- TSHR | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.369); catalogued as COSV53323510; called by muse, mutect2, varscan2
- TSPAN1 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs371861627, COSV64340861; called by muse, mutect2, varscan2
- TSSK1B | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101181172; called by muse, mutect2, varscan2
- TTC7B | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100128560; called by muse, mutect2, varscan2
- TTLL13P | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 106/401 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100296725; called by muse, mutect2, varscan2
- TTN | c.86015C>T p.S28672L (on ENST00000591111; = p.S21248L on NM_003319.4) | Missense Mutation (SNP) | VAF 12/89 reads (13%) | PolyPhen probably damaging (0.996); catalogued as COSV100629007; called by muse, mutect2, varscan2
- UGT2A2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs371537243; called by muse, mutect2, varscan2
- UGT2B28 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV59430877, COSV59434501; called by muse, mutect2, varscan2
- UNC13C | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52846044; called by muse, mutect2, varscan2
- UNC79 | c.3817G>A p.D1273N (on ENST00000393151 / NM_001346218.2; = p.D1096N on NM_020818.5) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV56405574; called by muse, mutect2, varscan2
- USP6 | c.4192G>A p.D1398N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100004855; called by muse, mutect2, varscan2
- VNN1 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100907844; called by muse, mutect2, varscan2
- VPS39 | c.764C>T p.P255L (on ENST00000348544 / NM_001301138.2; = p.P244L on NM_015289.5) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100529567; called by muse, mutect2, varscan2
- VWA8 | c.4155G>A p.W1385* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV101022679, COSV101022953; called by muse, mutect2, varscan2
- WAPL | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV100077245; called by muse, mutect2, varscan2
- WBP2NL | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 264/1716 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100173921; called by muse, mutect2, varscan2
- WDR11 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV99676971; called by muse, mutect2
- WDR17 | c.2484A>T p.R828S | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs1281622179, COSV99708241; called by muse, mutect2, varscan2
- WDR25 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100092279; called by muse, mutect2, varscan2
- WDR72 | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.588); catalogued as rs201559909, COSV64742066; called by muse, mutect2, varscan2
- WDR82 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.219); catalogued as rs1424345325, COSV99627219; called by muse, mutect2, varscan2
- WDR82 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.457); catalogued as COSV99627222; called by muse, mutect2, varscan2
- WNT3 | c.280A>T p.I94L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99843423; called by muse, mutect2, varscan2
- XDH | c.3067C>T p.H1023Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs772861663, COSV65148998; called by muse, mutect2, varscan2
- XIRP1 | c.4969C>T p.P1657S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV100453961; called by muse, mutect2, varscan2
- XIRP2 | c.3871G>A p.G1291R (on ENST00000628543; = p.G1466R on NM_152381.6) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99747126; called by muse, mutect2, varscan2
- XKR9 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs752979133, COSV68773220; called by muse, mutect2, varscan2
- ZBTB20 | c.436G>C p.V146L (on ENST00000474710 / NM_001164342.2; = p.V73L on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100615165; called by muse, mutect2, varscan2
- ZDHHC16 | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV61749759; called by muse, mutect2, varscan2
- ZNF235 | c.1253T>G p.L418R | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99349713; called by muse, mutect2, varscan2
- ZNF239 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100021916; called by muse, mutect2, varscan2
- ZNF415 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV99702005; called by muse, mutect2, varscan2
- ZNF442 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated, low confidence (0.82); PolyPhen possibly damaging (0.641); catalogued as COSV54421298; called by muse, mutect2, varscan2
- ZNF560 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100039023; called by muse, mutect2
- ZNF595 | c.600C>A p.Y200* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as rs1560094384; called by muse, mutect2
- ZNF638 | c.4717C>T p.P1573S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.996); catalogued as COSV52482314; called by muse, mutect2, varscan2
- ZNF695 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV60584775; called by muse, mutect2
- ZNF77 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV100094665; called by muse, mutect2, varscan2
- ZNF831 | c.3673C>T p.P1225S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV64041495; called by muse, mutect2, varscan2
- ZSCAN20 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV63683047; called by muse, mutect2, varscan2
- ZSWIM2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1263790725, COSV54573993; called by muse, mutect2, varscan2
- ABLIM2 | c.1825C>T p.L609F (on ENST00000341937 / NM_001130084.2; = p.L519F on NM_032432.5) | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2
- ADCY1 | c.3043C>T p.Q1015* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2
- ADD1 | c.1107del p.K369Nfs*32 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- GPR179 | c.2018G>A p.S673N (on ENST00000621958; = p.S672N on NM_001004334.4) | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC2 | c.3679A>T p.K1227* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- PHC1 | c.1218_1219del p.Q406Hfs*81 | Frame Shift Del (DEL) | VAF 17/119 reads (14%) | called by mutect2, pindel, varscan2
- RELCH | c.1825dup p.I609Nfs*2 | Frame Shift Ins (INS) | VAF 7/45 reads (16%) | called by mutect2, pindel
- SPATA31A3 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by mutect2, varscan2
- TUBGCP3 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- WNT9B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- ZFX | c.1819del p.C607Vfs*6 | Frame Shift Del (DEL) | VAF 21/45 reads (47%) | called by mutect2, pindel, varscan2
- ZNF26 | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ABCC3 | c.4158C>T p.P1386= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs1470555323, COSV99559784; called by muse, mutect2, varscan2
- ABL1 | c.2226C>T p.S742= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100584575; called by muse, mutect2, varscan2
- ABLIM1 | c.495G>A p.V165= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV99522689; called by muse, mutect2, varscan2
- ABLIM2 | c.1338G>A p.S446= (on ENST00000341937 / NM_001130084.2; = p.S394= on NM_032432.5) | Silent (SNP) | VAF 47/113 reads (42%) | catalogued as rs757149960, COSV56411520; called by muse, mutect2, varscan2
- ADAM21 | c.153G>A p.R51= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as rs746510077, COSV99961447; called by muse, mutect2, varscan2
- ADAM32 | c.936G>A p.L312= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV101165451, COSV101165502; called by muse, mutect2, varscan2
- ADAMTS6 | c.1266G>A p.T422= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs369383710; called by muse, mutect2, varscan2
- ADCK2 | c.1371C>T p.N457= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as rs754347728, COSV99301859; called by muse, mutect2, varscan2
- ADH1B | c.900G>A p.Q300= | Silent (SNP) | VAF 78/212 reads (37%) | catalogued as COSV100520667; called by muse, mutect2, varscan2
- AGAP4 | c.1923C>T p.A641= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as COSV101432708; called by muse, mutect2, varscan2
- ALPK3 | c.1260G>A p.L420= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs778227903, COSV99361938; called by muse, mutect2, varscan2
- ANK1 | c.735C>T p.I245= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs1183629505, COSV55900987; called by muse, mutect2, varscan2
- ARHGEF28 | c.1041C>T p.I347= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99710058; called by muse, mutect2, varscan2
- ASPM | c.6405T>C p.S2135= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as COSV99661086; called by muse, mutect2, varscan2
- BMPER | c.924C>T p.F308= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV51814742; called by muse, mutect2, varscan2
- BMPR2 | c.2568C>T p.T856= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV101001640; called by muse, mutect2, varscan2
- BTBD11 | c.144C>T p.G48= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs538152249, COSV99776946; called by muse, mutect2, varscan2
- BTBD11 | c.3153C>T p.L1051= (on ENST00000280758 / NM_001018072.2; = p.L588= on NM_001017523.2) | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV99776947; called by muse, mutect2, varscan2
- BTN2A1 | c.889C>T p.L297= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as COSV100438778; called by muse, mutect2, varscan2
- BTNL2 | c.159C>T p.L53= | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as COSV66631585; called by muse, mutect2, varscan2
- C1QTNF4 | c.75C>T p.S25= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100209396; called by muse, varscan2
- C6orf118 | c.423T>C p.T141= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as COSV100025136; called by muse, mutect2, varscan2
- C8orf34 | c.801C>T p.P267= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs1317365296, COSV100447838; called by muse, mutect2, varscan2
- CAVIN2 | c.786C>T p.I262= | Silent (SNP) | VAF 76/217 reads (35%) | catalogued as COSV58423231; called by muse, mutect2, varscan2
- CCR2 | c.219G>A p.L73= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV99432779; called by muse, mutect2, varscan2
- CDH12 | c.12G>A p.R4= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as rs766264616, COSV66420016; called by muse, mutect2, varscan2
- CDH15 | c.123C>T p.S41= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV99228848; called by muse, mutect2, varscan2
- CETN1 | c.210G>A p.K70= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1267385470, COSV100511404; called by muse, mutect2, varscan2
- CIAO2B | c.34C>T p.L12= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1013865591, COSV100399412; called by muse, mutect2, varscan2
- CIAO3 | c.180G>A p.R60= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV99285174; called by muse, mutect2, varscan2
- CNGA3 | c.210C>T p.I70= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs145057274; called by muse, mutect2, varscan2
- CNGA3 | c.1119G>A p.V373= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV99737422; called by muse, mutect2, varscan2
- CNTNAP2 | c.3483G>A p.G1161= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV62149926; called by muse, mutect2, varscan2
- CNTNAP3 | c.2517C>T p.F839= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99905606; called by muse, mutect2, varscan2
- COL4A3 | c.3963G>A p.K1321= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs776772531, COSV101170532; called by muse, mutect2, varscan2
- CPLANE1 | c.7897T>C p.L2633= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99951664; called by muse, mutect2
- CRB1 | c.2652C>T p.G884= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100958074; called by muse, mutect2, varscan2
- CYP2A13 | c.1248C>T p.F416= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as rs748438394, COSV57838183; called by muse, mutect2, varscan2
- DCAF1 | c.975C>T p.I325= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs782690059, COSV60043601; called by muse, mutect2, varscan2
- DENND2A | c.1668C>T p.L556= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99326971; called by muse, mutect2, varscan2
- DHFR2 | c.270T>A p.L90= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV100113462; called by muse, mutect2
- DIDO1 | c.180C>T p.S60= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99827064; called by muse, mutect2, varscan2
- DNAH17 | c.11034C>T p.S3678= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV101103410; called by muse, mutect2, varscan2
- DNAH3 | c.2739G>A p.L913= | Silent (SNP) | VAF 44/123 reads (36%) | catalogued as COSV99770475; called by muse, mutect2, varscan2
- DOK6 | c.879G>A p.K293= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV101234975; called by muse, mutect2, varscan2
- DUSP8 | c.978G>T p.G326= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100524520; called by muse, mutect2, varscan2
- DVL2 | c.735C>T p.P245= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV50037576; called by muse, mutect2, varscan2
- EGR2 | c.1119G>A p.R373= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as COSV54347607; called by muse, mutect2, varscan2
- EMILIN1 | c.2037G>A p.G679= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV99566532; called by muse, mutect2, varscan2
- EPS8L1 | c.1413G>A p.E471= (on ENST00000201647 / NM_133180.3; = p.E344= on NM_017729.3) | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV99137051; called by muse, mutect2, varscan2
- ERCC2 | c.570C>T p.C190= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99676006; called by muse, mutect2
- ERMARD | c.720C>T p.L240= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs769268820, COSV100824922; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAHD2A | c.258C>T p.A86= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs753482077, COSV99272261; called by muse, mutect2, varscan2
- FAM83B | c.2631C>T p.F877= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV100174991, COSV60919866; called by muse, mutect2, varscan2
- FAM83E | c.42C>T p.S14= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs749886755, COSV99320387; called by muse, mutect2, varscan2
- FAXC | c.120G>A p.G40= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV101067252; called by muse, mutect2, varscan2
- FCGBP | c.12570G>A p.A4190= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs868308653; called by muse, mutect2, varscan2
- FES | c.225G>A p.E75= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV99184786; called by muse, mutect2, varscan2
- FGD5 | c.3900G>A p.L1300= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV53240090; called by muse, mutect2, varscan2
- FGF11 | c.345C>T p.T115= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99548513; called by muse, mutect2, varscan2
- FLNB | c.6225C>T p.F2075= | Silent (SNP) | VAF 80/218 reads (37%) | catalogued as rs572257596, COSV55888170; ClinVar: likely benign; called by muse, mutect2, varscan2
- FREM1 | c.2310C>T p.I770= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs1323546250, COSV101085434; called by muse, mutect2, varscan2
- FRY | c.6393C>T p.S2131= | Silent (SNP) | VAF 59/133 reads (44%) | catalogued as COSV66570503; called by muse, mutect2, varscan2
- GALK2 | c.939C>T p.T313= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs890973376, COSV100509230; called by muse, mutect2
- GIMAP5 | c.312C>T p.Y104= | Silent (SNP) | VAF 60/135 reads (44%) | catalogued as COSV100500306; called by muse, mutect2, varscan2
- GIMAP5 | c.313C>T p.L105= | Silent (SNP) | VAF 59/134 reads (44%) | catalogued as COSV100500307; called by muse, mutect2, varscan2
- GJB6 | c.93C>T p.F31= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as COSV99576152; called by muse, mutect2, varscan2
- GLP2R | c.75C>T p.P25= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs763646550, COSV99302452; called by muse, varscan2
- GPR162 | c.555C>T p.L185= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV99163894; called by muse, mutect2, varscan2
- GRIK1 | c.1557A>G p.E519= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV100517869; called by muse, mutect2, varscan2
- GRIN3A | c.2145C>T p.S715= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV100701646, COSV100701816; called by muse, mutect2, varscan2
- GYS2 | c.2079G>A p.G693= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs1231384358, COSV99680238; called by muse, mutect2, varscan2
- HCN1 | c.2289G>A p.P763= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs759408275, COSV57502023; called by muse, mutect2, varscan2
- HCN1 | c.573C>T p.I191= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV57536693; called by muse, mutect2, varscan2
- HECW2 | c.3354C>T p.I1118= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV99648917; called by muse, mutect2, varscan2
- HIF3A | c.849C>T p.S283= (on ENST00000377670 / NM_152795.4; = p.S214= on NM_022462.4) | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as rs543522717, COSV99356047; called by muse, mutect2, varscan2
- HR | c.3426C>T p.S1142= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs374306253; called by muse, mutect2, varscan2
- HS3ST1 | c.531C>T p.F177= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV50027946; called by muse, mutect2, varscan2
- INPP4A | c.1242C>T p.I414= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV50849426; called by muse, mutect2, varscan2
- INPP5F | c.2400C>T p.L800= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100740379; called by muse, mutect2, varscan2
- INTS1 | c.2157C>T p.L719= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV101248316; called by muse, mutect2, varscan2
- IPO5 | c.37C>T p.L13= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99847662; called by muse, mutect2
- ITPR1 | c.3375C>T p.S1125= (on ENST00000354582; = p.S1110= on NM_002222.7) | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV100233118; called by muse, mutect2, varscan2
- KCNG1 | c.381C>T p.I127= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs1568799718, COSV65370069; called by muse, mutect2, varscan2
- KCNJ4 | c.582G>A p.S194= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as rs767497539, COSV57856578; called by muse, mutect2, varscan2
- KCNQ1 | c.846G>A p.L282= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV99328373; called by muse, mutect2, varscan2
- KCNQ2 | c.2361C>T p.S787= (on ENST00000359125 / NM_172107.4; = p.S759= on NM_004518.6) | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs1407459950, COSV100610539, COSV60556911; called by muse, varscan2
- KCNT1 | c.1110C>T p.F370= (on ENST00000488444; = p.F389= on NM_020822.3) | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as rs868420087, COSV53701673; called by muse, mutect2, varscan2
- KCNU1 | c.3141T>C p.N1047= | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as COSV101299421; called by muse, mutect2, varscan2
- KEL | c.1335G>A p.A445= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs751855900, COSV100786892, COSV62335129; called by muse, mutect2
- KIAA1549L | c.2232C>T p.L744= (on ENST00000321505; = p.L1041= on NM_012194.3) | Silent (SNP) | VAF 38/249 reads (15%) | catalogued as rs770973875, COSV99684366; called by muse, mutect2, varscan2
- KIF26A | c.2442C>T p.F814= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs371265576; called by muse, mutect2, varscan2
- KLKB1 | c.1098G>A p.G366= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as rs139190582; called by muse, mutect2, varscan2
- KNSTRN | c.96G>A p.R32= | Silent (SNP) | VAF 42/66 reads (64%) | catalogued as COSV51103425; called by muse, mutect2, varscan2
- KRT77 | c.849G>A p.V283= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100527266; called by muse, mutect2, varscan2
- KRTAP13-2 | c.162G>A p.R54= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs1250354455, COSV101299670, COSV101299681, COSV67762116; called by muse, mutect2, varscan2
- LEMD2 | c.1248G>A p.K416= | Silent (SNP) | VAF 71/303 reads (23%) | catalogued as rs1291219534, COSV99540901; called by muse, mutect2, varscan2
- MAGEA4 | c.615C>T p.I205= | Silent (SNP) | VAF 68/99 reads (69%) | catalogued as rs754718950, COSV52341984; called by muse, mutect2, varscan2
- MAGEE2 | c.801G>A p.L267= | Silent (SNP) | VAF 29/39 reads (74%) | catalogued as COSV100972972, COSV64898554; called by muse, mutect2, varscan2
- MAN2A2 | c.2025C>T p.V675= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV100847990; called by muse, mutect2, varscan2
- MAP3K8 | c.646C>T p.L216= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99552332; called by muse, mutect2, varscan2
- MAP7 | c.492C>T p.G164= | Silent (SNP) | VAF 69/208 reads (33%) | catalogued as COSV100644023; called by muse, mutect2, varscan2
- MAS1 | c.96C>T p.I32= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV99397002; called by muse, mutect2, varscan2
- MBD5 | c.3666C>T p.I1222= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV68699182; called by muse, mutect2, varscan2
- MCM2 | c.438C>T p.R146= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1028791399, COSV99413445; called by muse, mutect2, varscan2
- MEST | c.96A>G p.P32= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV99784411; called by muse, mutect2, varscan2
- MFSD4A | c.234G>A p.L78= | Silent (SNP) | VAF 20/187 reads (11%) | catalogued as COSV100901702; called by muse, mutect2, varscan2
- MGAT3 | c.279C>T p.L93= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs1044206604, COSV100362062, COSV57863840; called by muse, mutect2, varscan2
- MID2 | c.1902C>T p.F634= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs1376926695, COSV99464275; called by muse, mutect2, varscan2
- MOCS1 | c.1581C>T p.L527= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV99226935; called by muse, mutect2, varscan2
- MPEG1 | c.1638C>T p.S546= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99915926; called by muse, mutect2, varscan2
- MUC16 | c.20001C>T p.D6667= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV101201530; called by muse, mutect2, varscan2
- MUC17 | c.11493G>A p.E3831= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100074977; called by muse, mutect2, varscan2
- MYH14 | c.3387C>T p.S1129= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99222402, COSV99224045; called by muse, mutect2, varscan2
- MYH3 | c.3687C>T p.I1229= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as rs778389007, COSV56863746; called by muse, mutect2, varscan2
- MYO1H | c.2265G>A p.R755= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- MYO1H | c.2266A>C p.R756= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- MYOM2 | c.2553C>T p.F851= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV100038349; called by muse, mutect2, varscan2
- NCKAP1L | c.1599G>A p.V533= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs569946764, COSV53213225; called by muse, mutect2, varscan2
- NCOA3 | c.828G>A p.K276= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100508169; called by muse, mutect2, varscan2
- NEXMIF | c.3870C>T p.S1290= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as COSV99281814; called by muse, mutect2, varscan2
- NLRP1 | c.1308G>A p.A436= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs200867395, COSV52574053; called by muse, mutect2, varscan2
- NOD2 | c.1356C>T p.I452= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs186719861; called by muse, mutect2, varscan2
- NOL6 | c.654C>T p.P218= | Silent (SNP) | VAF 18/110 reads (16%) | catalogued as COSV99955181; called by muse, mutect2, varscan2
- NOTCH3 | c.2013C>T p.S671= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV99658741; called by muse, mutect2, varscan2
- NPAP1 | c.252C>T p.V84= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100276158; called by muse, mutect2, varscan2
- NPAP1 | c.2352C>T p.T784= | Silent (SNP) | VAF 50/198 reads (25%) | catalogued as rs1420335831, COSV61505105; called by muse, mutect2, varscan2
- OGDHL | c.1119G>A p.G373= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs1385143171, COSV100934502; called by muse, mutect2, varscan2
- OR1N1 | c.873G>A p.R291= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs756622437, COSV59195512; called by muse, mutect2, varscan2
- OR2T34 | c.504C>T p.T168= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100170545; called by muse, mutect2, varscan2
- OR4S2 | c.645C>T p.S215= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV100412802; called by muse, mutect2, varscan2
- OR5M1 | c.255C>T p.F85= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV73201948; called by muse, mutect2, varscan2
- OR5M11 | c.627C>T p.S209= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV73142030; called by muse, mutect2, varscan2
- OR6B3 | c.183C>T p.Y61= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as COSV60116753; called by muse, mutect2
- ORC6 | c.558C>T p.V186= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs750215085, COSV54624964; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDH18 | c.330G>A p.V110= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV61272821; called by muse, mutect2, varscan2
- PCDHA13 | c.192C>T p.F64= | Silent (SNP) | VAF 61/127 reads (48%) | catalogued as COSV99169693; called by muse, mutect2, varscan2
- PCDHB10 | c.447G>A p.G149= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as COSV99505013; called by muse, mutect2, varscan2
- PCLO | c.10485G>A p.G3495= | Silent (SNP) | VAF 55/94 reads (59%) | catalogued as rs1211934291, COSV61665213; called by muse, mutect2, varscan2
- PCLO | c.2988G>A p.V996= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV61619415; called by muse, mutect2, varscan2
- PDZRN3 | c.1884C>G p.A628= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as rs761131651, COSV55192807; called by muse, mutect2
- PEX2 | c.471C>T p.F157= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV63813334; called by muse, mutect2, varscan2
- PFKL | c.609C>T p.F203= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs746545423, COSV62463490; called by muse, mutect2, varscan2
- PIK3C2B | c.915C>T p.R305= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV100915083; called by muse, mutect2, varscan2
- PKDREJ | c.3174C>T p.L1058= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99479493; called by muse, mutect2, varscan2
- PLEKHG1 | c.2571C>T p.L857= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100651878; called by muse, mutect2, varscan2
- PNP | c.159C>T p.I53= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100829014; called by mutect2, varscan2
- POLE | c.3189C>T p.F1063= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100268131; called by muse, mutect2, varscan2
- POU5F2 | c.447C>T p.I149= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs1335420755, COSV67938546; called by muse, mutect2, varscan2
- PRKAA2 | c.1658G>A p.*553= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV100983069; called by muse, mutect2, varscan2
- PSMD9 | c.501C>T p.T167= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99945779; called by muse, mutect2, varscan2
- PXDNL | c.2757C>T p.L919= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV62492574, COSV62498168; called by muse, mutect2, varscan2
- RANBP3 | c.1440C>T p.T480= (on ENST00000340578 / NM_007322.3; = p.T475= on NM_003624.3) | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs755276608, COSV50381583, COSV99222181; called by muse, mutect2, varscan2
- RBM15B | c.2646G>A p.V882= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100082332; called by muse, mutect2, varscan2
- RELN | c.4683C>T p.S1561= | Silent (SNP) | VAF 54/102 reads (53%) | catalogued as COSV100634905; called by muse, mutect2, varscan2
- RHCG | c.459C>T p.I153= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs749867234, COSV99174252; called by muse, mutect2, varscan2
- RXFP1 | c.1074C>T p.I358= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100314179, COSV100314351; called by muse, mutect2, varscan2
- SCN10A | c.2748G>A p.R916= | Silent (SNP) | VAF 54/151 reads (36%) | catalogued as COSV101479532; called by muse, mutect2, varscan2
- SCN5A | c.4902C>T p.L1634= (on ENST00000333535 / NM_198056.3; = p.L1633= on NM_000335.5) | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV100350471; called by muse, mutect2, varscan2
- SELE | c.999C>T p.F333= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs267598160, COSV60978345; called by muse, mutect2, varscan2
- SEPTIN2 | c.897C>T p.F299= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV63632423; called by muse, mutect2, varscan2
- SERPINB7 | c.153C>T p.L51= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100321021; called by muse, mutect2, varscan2
- SERPINB9 | c.783G>A p.K261= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV101046730; called by muse, mutect2, varscan2
- SEZ6L | c.477C>T p.S159= | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV99962875; called by muse, mutect2, varscan2
- SEZ6L | c.2649C>T p.Y883= | Silent (SNP) | VAF 52/214 reads (24%) | catalogued as COSV99962876; called by muse, mutect2, varscan2
- SHANK1 | c.2001G>A p.Q667= | Silent (SNP) | VAF 42/161 reads (26%) | catalogued as COSV99521940, COSV99521998; called by muse, mutect2, varscan2
- SKIL | c.1299C>T p.S433= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as rs761243511, COSV99378525; called by muse, mutect2, varscan2
- SLC12A5 | c.1302C>T p.V434= (on ENST00000454036 / NM_001134771.2; = p.V411= on NM_020708.5) | Silent (SNP) | VAF 87/218 reads (40%) | catalogued as COSV99716794; called by muse, mutect2, varscan2
- SLC12A8 | c.2106C>T p.S702= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100103122; called by muse, mutect2
- SLC37A4 | c.324C>T p.F108= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV58155201; called by muse, mutect2, varscan2
- SLC43A3 | c.1158C>T p.P386= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100725264; called by muse, mutect2, varscan2
- SLC5A3 | c.1743C>T p.T581= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV100758079; called by muse, mutect2, varscan2
- SLC6A19 | c.1116C>T p.P372= | Silent (SNP) | VAF 48/252 reads (19%) | catalogued as rs149388719; called by muse, mutect2, varscan2
- SLCO4A1 | c.102C>G p.S34= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99415101; called by muse, mutect2, varscan2
- SLIT3 | c.909C>A p.A303= | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as COSV100269727; called by muse, mutect2
- SOHLH2 | c.606C>T p.I202= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100499219, COSV100499524; called by muse, varscan2
- SOHLH2 | c.546G>A p.R182= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1170117548, COSV58522072; called by muse, varscan2
- SPHKAP | c.630C>T p.I210= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1352896599, COSV60870460; called by muse, mutect2
- SPTBN2 | c.2959C>T p.L987= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV100020436; called by muse, mutect2, varscan2
- STAU2 | c.333C>T p.A111= (on ENST00000524300 / NM_001164380.2; = p.A79= on NM_014393.2) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100869140; called by muse, mutect2, varscan2
- SUCLG2 | c.1098C>T p.I366= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs1052001825, COSV56203414; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAS2R38 | c.666G>A p.R222= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV101516548; called by muse, mutect2, varscan2
- TBC1D17 | c.1341C>T p.L447= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs777694904, COSV99680919; called by muse, mutect2, varscan2
- TBCD | c.729C>T p.T243= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs372539410; called by muse, mutect2, varscan2
- TCF12 | c.867G>A p.T289= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs138618347; called by muse, mutect2, varscan2
- TELO2 | c.576C>T p.V192= | Silent (SNP) | VAF 58/121 reads (48%) | catalogued as rs1159673290, COSV99248702; called by muse, mutect2, varscan2
- THSD7B | c.372C>T p.V124= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV99757866; called by muse, mutect2, varscan2
- TMEM132B | c.1938G>A p.K646= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV54751134; called by muse, mutect2, varscan2
- TNS1 | c.2088C>T p.F696= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs1304341952, COSV99411841; called by muse, mutect2, varscan2
- TRANK1 | c.1827G>A p.R609= | Silent (SNP) | VAF 48/145 reads (33%) | catalogued as COSV100084686; called by muse, mutect2, varscan2
- TRAPPC13 | c.432G>A p.L144= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99198981; called by muse, mutect2, varscan2
- TRERF1 | c.2361C>T p.F787= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV100550764, COSV100551606; called by muse, mutect2, varscan2
- TRPM1 | c.3114G>A p.E1038= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99856619; called by muse, mutect2, varscan2
- TRPM6 | c.1491G>A p.V497= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs267602271, COSV100666947; called by muse, mutect2, varscan2
- TTC39C | c.1125C>T p.S375= (on ENST00000317571 / NM_001135993.2; = p.S314= on NM_153211.4) | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV58217178; called by muse, mutect2, varscan2
- TTLL2 | c.693C>T p.F231= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs779206805, COSV99514964; called by muse, mutect2, varscan2
- TXK | c.1149G>A p.R383= | Silent (SNP) | VAF 59/183 reads (32%) | catalogued as COSV99972783; called by muse, mutect2, varscan2
- UGT3A1 | c.76C>T p.L26= | Silent (SNP) | VAF 59/151 reads (39%) | catalogued as rs1254240252, COSV99955276; called by muse, mutect2, varscan2
- VEGFA | c.39C>T p.A13= (on ENST00000523873 / NM_001171623.1; = p.A193= on NM_003376.6) | Silent (SNP) | VAF 47/83 reads (57%) | catalogued as COSV100035557; called by muse, mutect2, varscan2
- VEGFA | c.474C>T p.S158= (on ENST00000523873 / NM_001171623.1; = p.S338= on NM_003376.6) | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as rs1191723777, COSV100035559; called by muse, mutect2, varscan2
- VIM | c.465G>A p.R155= | Silent (SNP) | VAF 2/17 reads (12%) | catalogued as rs1201028257, COSV99813200; called by muse, mutect2
- VWA8 | c.3471C>T p.F1157= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as rs1368154373, COSV64996472; called by muse, mutect2, varscan2
- XKR9 | c.1110C>T p.F370= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV68772516; called by muse, mutect2, varscan2
- ZBED9 | c.1965G>A p.R655= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as COSV71729743; called by muse, mutect2, varscan2
- ZEB1 | c.1344C>T p.P448= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100315000, COSV100315023; called by muse, mutect2, varscan2
- ZFHX3 | c.8307C>T p.S2769= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99214573; called by muse, mutect2, varscan2
- ZFHX4 | c.6963C>T p.F2321= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV50662831; called by muse, mutect2, varscan2
- ZIC2 | c.999C>T p.F333= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as COSV100891815; called by muse, mutect2, varscan2
- ZIM3 | c.60G>A p.G20= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV99518317; called by muse, mutect2, varscan2
- ZMIZ1 | c.1326C>T p.S442= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV100566537; called by muse, mutect2, varscan2
- ZNF638 | c.1173C>T p.S391= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as rs761194258, COSV100039904; called by muse, mutect2, varscan2
- ZNF768 | c.1464C>T p.A488= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs201223902, COSV63323586; called by muse, mutect2, varscan2
- ZNF8 | c.897C>T p.S299= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs759162125, COSV99544534; called by muse, mutect2, varscan2
- ZSCAN5B | c.276C>T p.F92= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV62838454; called by muse, mutect2, varscan2
- A1CF | c.100-6590G>A | Intron (SNP) | VAF 29/71 reads (41%) | catalogued as COSV99257638, COSV99257643; called by muse, mutect2, varscan2
- AL136982.4 | n.812C>T | RNA (SNP) | VAF 12/70 reads (17%) | catalogued as rs867876696; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83365C>T | Intron (SNP) | VAF 47/133 reads (35%) | called by muse, mutect2, varscan2
- ASS1 | c.773+63G>A | Intron (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- FRMPD2B | n.527G>A | RNA (SNP) | VAF 12/82 reads (15%) | called by mutect2, varscan2
- NACA | c.71-3044C>T | Intron (SNP) | VAF 45/103 reads (44%) | catalogued as COSV100771630; called by muse, mutect2, varscan2
- OPN4 | c.291-827C>T | Intron (SNP) | VAF 8/51 reads (16%) | catalogued as rs370346417, COSV54114835; called by muse, mutect2, varscan2
- OR51F2 | c.-12C>T | 5'UTR (SNP) | VAF 78/191 reads (41%) | catalogued as COSV100438148; called by muse, mutect2, varscan2
- RBM44 | c.-98-1631G>A | Intron (SNP) | VAF 5/15 reads (33%) | catalogued as rs766226653, COSV57630804; called by muse, mutect2
- RN7SL176P | chr12:100157595 C>T | 3'Flank (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- SSPOP | n.3030G>A | RNA (SNP) | VAF 14/21 reads (67%) | catalogued as COSV100022985; called by muse, mutect2, varscan2
- TGFB2 | c.346+16338C>T | Intron (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100860452; called by muse, mutect2, varscan2
- TIMM50 | chr19:39480816 G>A | 5'Flank (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100068085; called by muse, varscan2
- TPGS1 | c.-2A>C | 5'UTR (SNP) | VAF 12/18 reads (67%) | catalogued as COSV99298744; called by muse, mutect2, varscan2
- VKORC1 | chr16:31095459 G>A | 5'Flank (SNP) | VAF 3/14 reads (21%) | catalogued as rs1449273122, COSV100161851; called by muse, mutect2
